Somatic mutation profile of tumor specimen TCGA-EO-A3AS-01A (aliquot TCGA-EO-A3AS-01A-11D-A19Y-09) from TCGA case TCGA-EO-A3AS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 86.1 years (31,450 days).
Specimen TCGA-EO-A3AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04f4b268-fa91-4a24-b20f-efc0f2b3a2e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3AS-10A (Blood Derived Normal), aliquot TCGA-EO-A3AS-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2774b55c-2f7e-4d80-a53f-bf76c76fe0c2

The open-access MAF lists 180 somatic variants for this specimen: 142 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 34, Frame Shift Del 7, Nonsense Mutation 4, Splice Region 3, In Frame Del 3, Splice Site 3, RNA 2, Intron 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 22/28 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- ACP6 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.138); catalogued as COSV100984241; called by muse, mutect2, varscan2
- ALS2CL | c.2133G>T p.E711D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as COSV100015269; called by muse, mutect2, varscan2
- AOX1 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV101022200; called by muse, mutect2, varscan2
- AP1B1 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100434750; called by muse, mutect2, varscan2
- APBB3 | c.1367G>C p.G456A (on ENST00000357560 / NM_133173.2; = p.G463A on NM_006051.3) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as COSV100296660; called by muse, mutect2, varscan2
- ARHGAP22 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1426680496, COSV99985824, COSV99985994; called by muse, mutect2, varscan2
- ASB10 | c.931G>T p.E311* (on ENST00000420175 / NM_001142459.2; = p.E296* on NM_080871.4) | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99318879; called by muse, mutect2, varscan2
- ASXL2 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99711843; called by mutect2, varscan2
- BBS9 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs750504833, COSV99629579; called by muse, mutect2, varscan2
- BCAP31 | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.355); catalogued as COSV100798992; called by muse, mutect2, varscan2
- BCLAF1 | c.2737G>T p.D913Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as COSV50359878, COSV99219784; called by muse, mutect2, varscan2
- BFSP2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.866); catalogued as COSV100183784; called by muse, mutect2, varscan2
- BIRC6 | c.2223C>G p.D741E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428644, COSV70200606, COSV70205550; called by muse, mutect2, varscan2
- BRD8 | c.2222C>T p.A741V (on ENST00000254900 / NM_139199.2; = p.A814V on NM_006696.4) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50164783, COSV99137448; called by muse, mutect2, varscan2
- BTK | c.972A>C p.T324= | Splice Region (SNP) | VAF 26/32 reads (81%) | catalogued as COSV100437842; called by muse, mutect2, varscan2
- C19orf73 | c.364T>A p.C122S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99674573; called by muse, mutect2, varscan2
- CAMK2G | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99990187; called by muse, mutect2
- CASS4 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs1280406712, COSV64387198; called by muse, mutect2
- CDH4 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs370608791, COSV100849381; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3381G>C p.Q1127H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV100575698; called by muse, mutect2, varscan2
- CELSR3 | c.3052A>G p.I1018V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.456); catalogued as COSV99374675; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.657G>C p.K219N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99267498; called by muse, mutect2, varscan2
- CLCA4 | c.1390G>C p.A464P | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV99760745; called by muse, mutect2, varscan2
- CLDN10 | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100971189; called by muse, mutect2, varscan2
- COPZ1 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100017688; called by muse, mutect2, varscan2
- CPA1 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99163336; called by muse, mutect2, varscan2
- CPNE1 | c.1379A>G p.Q460R (on ENST00000352393; = p.Q465R on NM_003915.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100467966; called by muse, mutect2, varscan2
- CTDSP1 | c.408T>G p.D136E | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV99812076; called by muse, mutect2
- CTH | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); catalogued as COSV100697143; called by muse, mutect2, varscan2
- CUL3 | c.970C>G p.Q324E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100024610; called by muse, mutect2, varscan2
- DEPDC5 | c.2687G>A p.R896H (on ENST00000400246; = p.R965H on NM_014662.5) | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.267); catalogued as rs762596342, COSV99836273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as rs1273191233, COSV99826789; called by muse, mutect2, varscan2
- DIDO1 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as COSV99826795; called by muse, mutect2, varscan2
- DNAH7 | c.9000G>A p.W3000* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as rs992919354, COSV100416971; called by muse, mutect2, varscan2
- DNAJC5B | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99395867; called by muse, mutect2, varscan2
- EFCAB14 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100905659; called by muse, mutect2, varscan2
- EIF4E2 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99299282; called by muse, mutect2, varscan2
- ERICH3 | c.3082G>A p.D1028N | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV58608813; called by muse, mutect2, varscan2
- EVC2 | c.3363G>A p.E1121= | Splice Region (SNP) | VAF 20/21 reads (95%) | catalogued as COSV100186651; called by muse, mutect2, varscan2
- FAM124A | c.380C>T p.P127L (on ENST00000322475 / NM_001242312.2; = p.P163L on NM_145019.4) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696426; called by muse, mutect2, varscan2
- FN1 | c.6392A>C p.E2131A (on ENST00000359671 / NM_001365524.2; = p.E2100A on NM_002026.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as COSV100117989; called by muse, mutect2, varscan2
- FSD1 | c.949T>G p.S317A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99696985; called by muse, mutect2, varscan2
- FUT6 | c.753C>A p.H251Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99744876; called by muse, mutect2, varscan2
- GATA2 | c.1252T>A p.S418T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100351490; called by muse, mutect2, varscan2
- GRIN2B | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1477799075, COSV74206269; called by muse, mutect2, varscan2
- GSDMC | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99416417; called by muse, mutect2
- HECW1 | c.4131G>C p.L1377F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101223888; called by muse, mutect2, varscan2
- IL1RAPL2 | c.350T>A p.V117D | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100781832; called by muse, mutect2, varscan2
- ITPR3 | c.161-1G>C p.X54_splice | Splice Site (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100967970; called by muse, mutect2, varscan2
- JCAD | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1358421026, COSV64761982; called by muse, mutect2, varscan2
- KIAA1109 | c.6410A>G p.K2137R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV99170076; called by muse, mutect2, varscan2
- KIF5A | c.1696G>A p.G566S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV54051413, COSV99673427; called by muse, mutect2, varscan2
- KIR2DL1 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV52412428, COSV99383527; called by muse, mutect2, varscan2
- LARP6 | c.1285G>C p.G429R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV100151016, COSV54581405; called by muse, mutect2, varscan2
- LETM2 | c.799A>C p.K267Q (on ENST00000379957 / NM_001286819.2; = p.K172Q on NM_144652.3) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99907585; called by muse, mutect2, varscan2
- LMCD1 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774131217, COSV99337778; called by muse, mutect2
- LRP2 | c.4876G>C p.D1626H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV55562035; called by muse, mutect2, varscan2
- LYZL1 | c.144G>T p.K48N (on ENST00000375500; = p.K2N on NM_032517.6) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100973675; called by muse, mutect2
- MAMDC4 | c.3164G>C p.W1055S (on ENST00000445819; = p.W976S on NM_206920.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99808228; called by muse, mutect2
- METTL6 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV101085083; called by muse, mutect2, varscan2
- MISP | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV53119621, COSV99297084; called by muse, mutect2, varscan2
- MKI67 | c.3589A>G p.K1197E | Missense Mutation (SNP) | VAF 91/123 reads (74%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as rs779684067, COSV100896902; called by muse, mutect2, varscan2
- MSC | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV100335853; called by muse, mutect2, varscan2
- MTSS1 | c.1930A>T p.S644C | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV99412950; called by muse, mutect2
- NAALAD2 | c.997A>G p.R333G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV100428718; called by muse, mutect2, varscan2
- NF2 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV100099147; called by muse, mutect2, varscan2
- NFASC | c.1007C>G p.A336G (on ENST00000339876 / NM_001378329.1; = p.A347G on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100365302; called by muse, mutect2, varscan2
- NFE2L3 | c.1686C>G p.F562L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99283947, COSV99283962; called by muse, mutect2
- NSMAF | c.751A>T p.M251L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99233331, COSV99233370; called by muse, mutect2, varscan2
- NYAP2 | c.780C>A p.D260E | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99798090; called by muse, mutect2, varscan2
- OR13D1 | c.740T>A p.F247Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.925); catalogued as COSV59513859, COSV59514600; called by muse, mutect2, varscan2
- OR1S2 | c.114C>G p.N38K | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100224344; called by muse, mutect2, varscan2
- OTOF | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV99718681; called by muse, mutect2, varscan2
- PCDHB8 | c.1507T>A p.S503T | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99177264; called by muse, mutect2, varscan2
- PCDHGA5 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.208); catalogued as COSV99544908; called by muse, mutect2, varscan2
- PCDHGB2 | c.804C>A p.D268E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99544906; called by muse, mutect2, varscan2
- PCNX1 | c.3889T>C p.Y1297H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99455995, COSV99456865; called by muse, mutect2, varscan2
- PCSK5 | c.3425G>T p.G1142V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV101377686; called by muse, mutect2, varscan2
- PDE6B | c.1561A>G p.I521V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV99728241; called by muse, mutect2, varscan2
- PEX11G | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55536522; called by muse, mutect2, varscan2
- PKD1 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs749397025, COSV99237929; called by muse, mutect2, varscan2
- PNPLA6 | c.1353A>C p.E451D (on ENST00000414982 / NM_001166111.2; = p.E403D on NM_006702.5) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.987); catalogued as COSV99654322; called by muse, mutect2, varscan2
- POLH | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100947857; called by muse, mutect2, varscan2
- PRDM14 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV99400439; called by muse, mutect2, varscan2
- PREP | c.1811T>G p.L604R (on ENST00000369110; = p.L670R on NM_002726.5) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100964102; called by muse, mutect2, varscan2
- PRR23B | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs759081677, COSV61493889; called by muse, mutect2, varscan2
- PRRG4 | c.450C>T p.C150= | Splice Region (SNP) | VAF 16/26 reads (62%) | catalogued as rs551757808, COSV99141422; called by muse, mutect2, varscan2
- PTEN | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; called by muse, mutect2, varscan2
- RABEP2 | c.433-2A>T p.X145_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100707190; called by muse, mutect2, varscan2
- RASSF2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs750068371, COSV101040898; called by muse, mutect2, varscan2
- RFX6 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as rs780273514, COSV60587947; called by muse, mutect2, varscan2
- RORC | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as CM158000, COSV100562072, COSV59094013; called by muse, mutect2, varscan2
- RRM2B | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99310391; called by muse, mutect2, varscan2
- RYR3 | c.1939T>A p.F647I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101213957; called by muse, mutect2, varscan2
- SCNN1G | c.209A>C p.Q70P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100264428, COSV55598553; called by muse, mutect2, varscan2
- SEMA6C | c.136T>C p.W46R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.986); catalogued as COSV100501529; called by muse, mutect2, varscan2
- SENP7 | c.2956C>G p.Q986E | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100053752, COSV58622052; called by muse, mutect2, varscan2
- SH3PXD2B | c.1768C>G p.L590V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100288405; called by muse, mutect2, varscan2
- SLC1A5 | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV101314813; called by muse, mutect2, varscan2
- SLC39A10 | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660741; called by muse, mutect2
- SLC6A16 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs750131243, COSV100242684, COSV100242903; called by muse, mutect2, varscan2
- SLCO2B1 | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374600854; called by muse, mutect2, varscan2
- SLFN5 | c.1862T>A p.F621Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.009); catalogued as COSV100249780; called by muse, mutect2, varscan2
- SPAG9 | c.2723T>G p.I908S (on ENST00000262013 / NM_001130528.3; = p.I894S on NM_003971.6) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV100005752; called by muse, mutect2, varscan2
- SPATA16 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV100651529; called by muse, mutect2, varscan2
- SSB | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV99641851; called by muse, mutect2, varscan2
- STK4 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV100860416; called by muse, mutect2, varscan2
- TACR1 | c.192G>T p.R64S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100538119; called by muse, mutect2, varscan2
- TCF7L1 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1420696258, COSV99964703; called by muse, mutect2, varscan2
- TESK1 | c.716A>T p.D239V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52412245, COSV99427586; called by muse, mutect2, varscan2
- TFR2 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99355711; called by muse, mutect2, varscan2
- TG | c.6056G>T p.G2019V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as rs757874903, COSV99602699; called by muse, mutect2, varscan2
- TGM6 | c.1644T>A p.H548Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99172413; called by muse, mutect2, varscan2
- TIMM50 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100068064; called by muse, mutect2, varscan2
- TMC6 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100130315; called by muse, mutect2, varscan2
- TMEM202 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100499236; called by muse, mutect2, varscan2
- TOR1AIP1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as COSV99621505, COSV99621586; called by muse, mutect2, varscan2
- TRIP12 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.037); catalogued as COSV99390819; called by muse, mutect2, varscan2
- UGGT1 | c.1310T>G p.V437G | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99391054; called by muse, mutect2, varscan2
- UNC5A | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99994992; called by muse, mutect2, varscan2
- VIT | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs1411675853, COSV101007689; called by muse, mutect2, varscan2
- VLDLR | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101173626, COSV66077148; called by muse, mutect2
- ZDHHC18 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100938866; called by muse, mutect2, varscan2
- ZHX2 | c.1802G>A p.G601D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as COSV100073754, COSV58714442; called by muse, mutect2, varscan2
- ZMYND8 | c.3200C>A p.T1067N (on ENST00000311275 / NM_001363741.2; = p.T1041N on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV53688669, COSV99521148; called by muse, mutect2, varscan2
- ZNF85 | c.1041T>G p.C347W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100060069; called by muse, mutect2, varscan2
- ZXDB | c.2125C>A p.L709M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100886021; called by muse, mutect2, varscan2
- CENPJ | c.3720dup p.G1241Wfs*9 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- FAM217B | c.1093_1126del p.S366Kfs*6 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel
- GARS1 | c.1455_1466del p.L486_P489del | In Frame Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- GUCY1B1 | c.988_1005del p.L330_R335del | In Frame Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- IGLV2-8 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ISL2 | c.1037_1047del p.P346Qfs*146 | Frame Shift Del (DEL) | VAF 55/79 reads (70%) | called by mutect2, pindel, varscan2
- ITGAD | c.1731_1743delinsAA p.P578Ifs*86 | Frame Shift Del (DEL) | VAF 34/87 reads (39%) | called by pindel, varscan2*
- LYZL2 | c.144G>T p.K48N (on ENST00000375318; = p.K2N on NM_183058.3) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2
- OR13F1 | c.810_817del p.D271Yfs*18 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- OTOF | c.3754_3760del p.R1252Cfs*16 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- PTCH1 | c.1351del p.A451Pfs*5 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- SLC25A17 | c.284_301del p.K95_T100del | In Frame Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- TEX10 | c.1168_1183del p.D390Lfs*2 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1655T>C p.F552S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ACAD10 | c.3093C>T p.T1031= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs749427970, COSV100564515; called by muse, mutect2, varscan2
- ACAN | c.555T>G p.P185= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100719029; called by muse, mutect2, varscan2
- ACVR1B | c.316T>C p.L106= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99231839; called by muse, mutect2, varscan2
- AHSA1 | c.174G>A p.V58= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV99376181; called by muse, mutect2, varscan2
- AK9 | c.852T>A p.L284= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV99572718; called by muse, mutect2, varscan2
- ATP11B | c.2952G>A p.G984= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100018027, COSV60030671; called by muse, mutect2, varscan2
- ATP13A2 | c.709C>T p.L237= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV58701943; called by muse, mutect2, varscan2
- BEND7 | c.1311C>G p.V437= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as rs749761993, COSV100346966; called by muse, mutect2, varscan2
- CEP170 | c.3801C>A p.R1267= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs973625873, COSV100317684; called by muse, mutect2, varscan2
- CYP2J2 | c.333C>A p.R111= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as COSV100967979, COSV100968115; called by muse, mutect2, varscan2
- EPHA8 | c.549G>A p.L183= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as COSV51262806, COSV99385502; called by muse, mutect2, varscan2
- FASN | c.39G>T p.L13= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100148228; called by muse, mutect2, varscan2
- GDE1 | c.570T>C p.Y190= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs765880282, COSV100783224; called by muse, mutect2
- GSN | c.276C>T p.G92= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs774617795, COSV57997291; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDDC2 | c.543C>G p.V181= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100600274; called by muse, mutect2, varscan2
- HECW2 | c.2875A>C p.R959= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV99648479; called by muse, mutect2, varscan2
- HSPH1 | c.2097C>T p.G699= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100185109; called by muse, mutect2, varscan2
- IL3 | c.420G>A p.A140= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs781087044, COSV99735426; called by muse, mutect2, varscan2
- ITGAX | c.2496G>A p.V832= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs770781987, COSV99191971; called by muse, mutect2, varscan2
- LIFR | c.2535A>T p.A845= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99665229; called by muse, mutect2, varscan2
- LINS1 | c.882T>C p.F294= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as COSV100130459; called by muse, mutect2, varscan2
- LMNTD1 | c.150G>A p.L50= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV51448385; called by muse, mutect2, varscan2
- MAN2A1 | c.1665A>G p.A555= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99811698; called by muse, mutect2, varscan2
- MYO18B | c.3501C>T p.S1167= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs1569103100, COSV59152113; called by muse, mutect2, varscan2
- OTOF | c.804C>A p.G268= | Silent (SNP) | VAF 51/69 reads (74%) | catalogued as COSV99718678; called by muse, mutect2, varscan2
- RBP3 | c.1740G>A p.P580= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs140857967; called by muse, mutect2, varscan2
- RFX6 | c.1722T>C p.F574= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100264155; called by muse, varscan2
- SLC20A2 | c.1341G>A p.A447= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs1014539937, COSV60603131; called by muse, mutect2, varscan2
- SLC4A5 | c.2532C>T p.I844= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as COSV100697947; called by muse, mutect2, varscan2
- SLC5A10 | c.420G>A p.L140= | Silent (SNP) | VAF 38/47 reads (81%) | catalogued as COSV100525440; called by muse, mutect2, varscan2
- TMEM132B | c.747C>G p.P249= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100170636; called by muse, mutect2, varscan2
- TRPV5 | c.1806G>A p.V602= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99520909; called by muse, mutect2, varscan2
- ZNF615 | c.363C>T p.F121= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV65032471; called by muse, mutect2, varscan2
- ZNF669 | c.1170T>C p.Y390= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100594321; called by muse, mutect2, varscan2
- KIR3DX1 | n.910C>G | RNA (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99683582; called by muse, mutect2, varscan2
- MACF1 | c.15832-10109C>T | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99246265; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640607 G>C | 3'Flank (SNP) | VAF 35/66 reads (53%) | catalogued as COSV99194861; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2643C>T | RNA (SNP) | VAF 17/40 reads (43%) | catalogued as rs778682367; called by muse, mutect2, varscan2
